Somatic mutation profile of tumor specimen MMRF_1659_4_BM_CD138pos (aliquot MMRF_1659_4_BM_CD138pos_T1_KHS5U_L12904) from MMRF case MMRF_1659, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.0 years (18,618 days).
Specimen MMRF_1659_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b13c13aa-c62b-4683-a625-9bdc9872f372.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1659_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1659_2_PB_Whole_C1_KBS5U_L04831; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b78392e-6290-4c9c-9086-ecfe657f2b62

The open-access MAF lists 134 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, 3'UTR 37, Silent 16, Intron 11, 3'Flank 3, 5'UTR 3, Nonsense Mutation 2, RNA 2, 5'Flank 2, Frame Shift Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1BG | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs1280350283, COSV99568395; called by muse, mutect2, varscan2
- C2orf16 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as COSV68646836; called by muse, mutect2, varscan2
- CACNA1I | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as rs1196906789, COSV60807504; called by muse, mutect2, varscan2
- CANX | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as rs775569975; called by muse, mutect2, varscan2
- CNTN3 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 73/120 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1388559105; called by muse, mutect2, varscan2
- CNTN6 | c.1253dup p.S419Vfs*33 | Frame Shift Ins (INS) | VAF 46/196 reads (23%) | catalogued as rs758676375; called by mutect2, varscan2
- FAM151B | c.444A>C p.K148N | Missense Mutation (SNP) | VAF 130/218 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV56474476; called by muse, mutect2, varscan2
- GALNTL6 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs756041431; called by muse, mutect2, varscan2
- HM13 | c.799G>C p.V267L | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59437482; called by muse, mutect2, varscan2
- HNF1B | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374126219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-70 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371486752; called by muse, varscan2
- IGHV5-51 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs549973566; called by muse, varscan2
- IQCH | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 219/669 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99971954; called by muse, mutect2, varscan2
- IRAK1 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs782207964; called by muse, mutect2, varscan2
- KLK10 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs755105316; called by muse, mutect2, varscan2
- MRGPRF | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs759247107, COSV104396050, COSV57995980; called by muse, mutect2, varscan2
- NEURL1B | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs1435562072, COSV63940375; called by muse, mutect2, varscan2
- OR13C3 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV101053300, COSV66166122; called by muse, mutect2, varscan2
- RNF113B | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1167910497, COSV57434659; called by muse, mutect2, varscan2
- ROBO1 | c.3971C>T p.T1324M | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1045339363, COSV71392720, COSV71397929; called by muse, mutect2, varscan2
- RPS9 | c.-25-8C>T | Splice Region (SNP) | VAF 28/137 reads (20%) | catalogued as COSV100256467; called by muse, mutect2, varscan2
- SPO11 | c.1002G>T p.R334S | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100625710; called by muse, mutect2, varscan2
- TNK2 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs751954076, COSV57365555; called by muse, mutect2, varscan2
- TRAF3IP3 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV50551452, COSV50551537; called by muse, mutect2, varscan2
- UMOD | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs773293322; called by muse, mutect2, varscan2
- UNC5A | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs149303258; called by muse, mutect2, varscan2
- USP29 | c.2658del p.I887Ffs*6 | Frame Shift Del (DEL) | VAF 35/158 reads (22%) | catalogued as COSV54146677; called by mutect2, pindel, varscan2
- VPS13D | c.13090G>A p.A4364T | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1341144908; called by muse, mutect2, varscan2
- ZNF493 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100828552, COSV62749591; called by muse, mutect2, varscan2
- ABCC6 | c.1721T>C p.L574P | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ASH1L | c.3877G>A p.E1293K | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- C17orf98 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CABIN1 | c.3478C>G p.Q1160E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CCDC152 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CCDC96 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 138/282 reads (49%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.216); called by mutect2, varscan2
- CFHR2 | c.737A>T p.H246L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DTX1 | c.46_60del p.G16_Q20del | In Frame Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- ESRP1 | c.1383C>G p.I461M | Missense Mutation (SNP) | VAF 89/146 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM189A1 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GIPC3 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV6-57 | c.326A>C p.Y109S | Missense Mutation (SNP) | VAF 164/186 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- KCNH8 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT76 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 52/104 reads (50%) | called by muse, mutect2, varscan2
- LEXM | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MOXD1 | c.571A>T p.N191Y | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MRPL54 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYEOV | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 100/434 reads (23%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NETO1 | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 56/437 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PSME1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- SAFB | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 61/318 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SLF1 | c.2626G>T p.V876L | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SMAD6 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 216/565 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK35 | c.953G>A p.C318Y | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNJ2 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TACC2 | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by mutect2, varscan2
- TCHH | c.16A>T p.R6* | Nonsense Mutation (SNP) | VAF 28/119 reads (24%) | called by muse, mutect2, varscan2
- USPL1 | c.1158G>T p.W386C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMIZ2 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 113/185 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF157 | c.251A>C p.E84A | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ZNF462 | c.6900C>A p.F2300L | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD18A | c.144G>T p.A48= | Silent (SNP) | VAF 39/117 reads (33%) | called by muse, mutect2, varscan2
- CCR6 | c.612C>T p.V204= | Silent (SNP) | VAF 57/132 reads (43%) | called by muse, mutect2, varscan2
- ERVV-2 | c.1110C>T p.L370= | Silent (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- HAS1 | c.1557C>A p.R519= | Silent (SNP) | VAF 20/84 reads (24%) | called by muse, varscan2
- IGHV5-51 | c.60G>A p.E20= | Silent (SNP) | VAF 73/202 reads (36%) | catalogued as rs75660488; called by muse, varscan2
- INAVA | c.1425C>T p.P475= | Silent (SNP) | VAF 126/225 reads (56%) | catalogued as rs201583008, COSV66256355; called by muse, mutect2, varscan2
- MEGF6 | c.3432T>C p.T1144= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- OVOL1 | c.453C>T p.C151= | Silent (SNP) | VAF 78/544 reads (14%) | catalogued as rs545994680; called by muse, mutect2, varscan2
- PIEZO2 | c.1158G>A p.R386= | Silent (SNP) | VAF 45/177 reads (25%) | called by muse, mutect2, varscan2
- POU2F3 | c.93G>A p.E31= | Silent (SNP) | VAF 130/281 reads (46%) | catalogued as rs777939631; called by muse, mutect2, varscan2
- QKI | c.63G>A p.L21= | Silent (SNP) | VAF 75/178 reads (42%) | called by muse, varscan2
- RGS19 | c.504G>A p.K168= | Silent (SNP) | VAF 100/198 reads (51%) | called by muse, mutect2, varscan2
- SH3TC2 | c.2298G>A p.V766= | Silent (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- TIAM1 | c.4125G>A p.L1375= | Silent (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- TMX3 | c.1347A>G p.L449= | Silent (SNP) | VAF 70/173 reads (40%) | catalogued as rs769144543; called by muse, mutect2, varscan2
- ZSCAN29 | c.1944G>A p.E648= | Silent (SNP) | VAF 62/298 reads (21%) | catalogued as rs1163160654; called by muse, mutect2, varscan2
- ABCC4 | c.*748A>G | 3'UTR (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.*1763A>C | 3'UTR (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- AGR2 | c.*399C>T | 3'UTR (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- ATRNL1 | c.*3942T>A | 3'UTR (SNP) | VAF 16/56 reads (29%) | catalogued as COSV58072376; called by muse, mutect2, varscan2
- BBS1 | c.1339+107G>A | Intron (SNP) | VAF 56/185 reads (30%) | catalogued as rs760183317; called by muse, mutect2, varscan2
- BCAT1 | c.*5564T>C | 3'UTR (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- BLOC1S5 | c.*442G>A | 3'UTR (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- BTN3A1 | c.*541G>A | 3'UTR (SNP) | VAF 103/211 reads (49%) | called by muse, mutect2, varscan2
- C6orf120 | c.*228T>A | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- CORO2A | c.*1022G>A | 3'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2
- DIO2 | c.*4389C>G | 3'UTR (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- DNAH10 | c.9645-857C>T | Intron (SNP) | VAF 57/181 reads (31%) | catalogued as rs1278003723; called by muse, mutect2, varscan2
- EIF2AK3 | c.*512A>G | 3'UTR (SNP) | VAF 21/74 reads (28%) | catalogued as rs1198192467; called by muse, mutect2, varscan2
- EVC | c.1563+1914G>A | Intron (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- FAM182B | n.1200C>T | RNA (SNP) | VAF 4/8 reads (50%) | catalogued as rs879142727; called by mutect2, varscan2
- FOXI1 | c.*181C>A | 3'UTR (SNP) | VAF 38/132 reads (29%) | called by muse, mutect2, varscan2
- FOXL1 | c.*1365_*1379del | 3'UTR (DEL) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- GABRB3 | c.241-20933C>T | Intron (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- GAPVD1 | c.3047-210A>C | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- HMGA2 | c.282+2158A>T | Intron (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- HSF4 | c.1255-80G>T | Intron (SNP) | VAF 6/25 reads (24%) | catalogued as rs530911272; called by muse, mutect2, varscan2
- IFT80 | c.*317T>C | 3'UTR (SNP) | VAF 57/165 reads (35%) | called by muse, mutect2, varscan2
- IRF9 | c.*151G>T | 3'UTR (SNP) | VAF 55/131 reads (42%) | called by muse, mutect2, varscan2
- IZUMO3 | chr9:24545935 C>A | 5'Flank (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2
- KIF21B | chr1:200970213 T>A | 3'Flank (SNP) | VAF 62/235 reads (26%) | called by muse, mutect2, varscan2
- KRTAP2-1 | c.*74G>A | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- LILRA1 | c.*585G>T | 3'UTR (SNP) | VAF 91/344 reads (26%) | catalogued as rs189371015; called by muse, mutect2, varscan2
- LRRC28 | c.*1312G>A | 3'UTR (SNP) | VAF 98/257 reads (38%) | catalogued as rs771171841, COSV57343172; called by muse, mutect2, varscan2
- MBL2 | c.*1892C>T | 3'UTR (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- MLLT3 | c.*3398A>G | 3'UTR (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- MLPH | c.*553C>A | 3'UTR (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- MMP27 | c.*6T>C | 3'UTR (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- MUC21 | c.*250C>T | 3'UTR (SNP) | VAF 26/102 reads (25%) | catalogued as rs760272681; called by muse, mutect2, varscan2
- MXD3 | chr5:177305703 C>G | 3'Flank (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- NDN | c.*527G>A | 3'UTR (SNP) | VAF 43/140 reads (31%) | catalogued as rs997240609; called by muse, mutect2, varscan2
- NKTR | c.*867G>T | 3'UTR (SNP) | VAF 17/88 reads (19%) | catalogued as COSV51775284; called by muse, mutect2, varscan2
- NMRK1 | c.*2G>A | 3'UTR (SNP) | VAF 72/294 reads (24%) | catalogued as COSV100738049; called by muse, mutect2, varscan2
- NRXN1 | c.-685T>A | 5'UTR (SNP) | VAF 37/129 reads (29%) | called by muse, mutect2, varscan2
- NSD3 | c.1856-1345T>C | Intron (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- NSL1 | c.*11353C>T | 3'UTR (SNP) | VAF 18/63 reads (29%) | catalogued as rs371938400; called by muse, mutect2, varscan2
- OTX2 | c.*266C>T | 3'UTR (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- PRAM1 | c.*18C>T | 3'UTR (SNP) | VAF 35/118 reads (30%) | called by muse, mutect2, varscan2
- QKI | c.-49G>A | 5'UTR (SNP) | VAF 10/40 reads (25%) | called by muse, varscan2
- RPL18A | c.329-81C>T | Intron (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- SESN3 | c.*5786del | 3'UTR (DEL) | VAF 36/180 reads (20%) | catalogued as rs909803134; called by mutect2, pindel, varscan2
- SMG1 | c.*4455G>A | 3'UTR (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- SMG5 | c.*1082G>A | 3'UTR (SNP) | VAF 56/202 reads (28%) | called by muse, mutect2, varscan2
- SOWAHA | c.*578T>C | 3'UTR (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- SPTLC1 | c.-31T>C | 5'UTR (SNP) | VAF 43/147 reads (29%) | called by muse, mutect2, varscan2
- TBX3 | chr12:114683787 C>A | 5'Flank (SNP) | VAF 28/72 reads (39%) | called by mutect2, varscan2
- TH | c.406-18C>A | Intron (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- TRIM35 | c.*2480G>A | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- UBASH3B | c.*323A>C | 3'UTR (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- VEGFA | c.546-85T>A | Intron (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- VEZT | c.*431_*434del | 3'UTR (DEL) | VAF 6/22 reads (27%) | called by pindel, varscan2
- WTAP | chr6:159761070 ins T | 3'Flank (INS) | VAF 27/45 reads (60%) | called by mutect2, pindel, varscan2
- ZFPM2 | n.274G>T | RNA (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- ZNF516 | c.*1389T>A | 3'UTR (SNP) | VAF 71/114 reads (62%) | catalogued as COSV71587697; called by muse, mutect2, varscan2
